Somatic mutation profile of tumor specimen 0DHZS3 from CCDI case PBBUYU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.3 years (5,240 days).
Specimen 0DHZS3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6157909-2d32-408e-a64e-174cbb9d3a00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHZRS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ede6f46-580a-469c-8573-f0d71bee2c90

The open-access MAF lists 37 somatic variants for this specimen: 32 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Nonsense Mutation 3, Silent 2, Splice Site 1, 3'Flank 1, 5'UTR 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 233/910 reads (26%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 16/411 reads (4%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2
- DDX3X | c.973C>T p.R325C (on ENST00000399959; = p.R326C on NM_001356.5) | Missense Mutation (SNP) | VAF 60/1116 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs1555953548, COSV67863531; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 40/558 reads (7%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABLIM3 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 35/586 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs979930405; called by muse, mutect2
- CTNNB1 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 264/935 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62688590; called by muse, mutect2, varscan2
- DDX3X | c.1147A>G p.T383A (on ENST00000399959; = p.T384A on NM_001356.5) | Missense Mutation (SNP) | VAF 20/540 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67863246; called by muse, mutect2
- FSIP2 | c.8038A>G p.T2680A | Missense Mutation (SNP) | VAF 68/910 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.398); catalogued as COSV58079345; called by muse, mutect2
- HNF4G | c.224C>T p.A75V (on ENST00000354370 / NM_001330561.2; = p.A122V on NM_004133.5) | Missense Mutation (SNP) | VAF 81/314 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); catalogued as rs770285159, COSV62972179; called by muse, mutect2, varscan2
- KCNS1 | c.1397G>T p.R466L | Missense Mutation (SNP) | VAF 112/448 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as CM1111452, COSV60259936; called by muse, mutect2, varscan2
- KIAA1549L | c.569C>A p.S190Y (on ENST00000321505; = p.S487Y on NM_012194.3) | Missense Mutation (SNP) | VAF 123/575 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV104377835, COSV55776788; called by muse, mutect2, varscan2
- MAGEB6 | c.634A>G p.K212E | Missense Mutation (SNP) | VAF 339/1057 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.376); catalogued as COSV66872746; called by muse, mutect2, varscan2
- PRB4 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 213/684 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as rs374434768, COSV99686470; called by muse, mutect2, varscan2
- RADIL | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 163/647 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs377167416; called by muse, mutect2, varscan2
- RGL4 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 162/522 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs773973116; called by muse, mutect2, varscan2
- RHBDF2 | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 42/568 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs369966353; called by muse, mutect2
- RPL22 | c.143A>G p.K48R | Missense Mutation (SNP) | VAF 141/529 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV52377767; called by muse, mutect2, varscan2
- RYR1 | c.10495C>T p.R3499W | Missense Mutation (SNP) | VAF 203/665 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs147058802; called by muse, mutect2, varscan2
- TAOK3 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 20/455 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537291817, COSV66827587; called by muse, mutect2
- WNK2 | c.1405G>A p.G469S | Missense Mutation (SNP) | VAF 18/632 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1456594752; called by muse, mutect2
- AMER1 | c.2581G>A p.G861S | Missense Mutation (SNP) | VAF 195/656 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ARID1A | c.3077G>C p.R1026P | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- AXIN2 | c.2486dup p.M830Dfs*3 | Frame Shift Ins (INS) | VAF 256/959 reads (27%) | called by mutect2, pindel, varscan2
- BOP1 | c.1310T>A p.L437Q | Missense Mutation (SNP) | VAF 28/600 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- CYTH3 | c.214A>G p.M72V | Missense Mutation (SNP) | VAF 28/828 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- EHBP1 | c.546C>A p.D182E | Missense Mutation (SNP) | VAF 90/488 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FSIP2 | c.13376T>C p.L4459P | Missense Mutation (SNP) | VAF 33/545 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GPR179 | c.6385G>T p.A2129S (on ENST00000621958; = p.A2128S on NM_001004334.4) | Missense Mutation (SNP) | VAF 262/906 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- HES2 | c.495C>A p.C165* | Nonsense Mutation (SNP) | VAF 22/871 reads (3%) | called by muse, mutect2
- MATN2 | c.835+2_835+5del p.X279_splice | Splice Site (DEL) | VAF 40/470 reads (9%) | called by mutect2, pindel
- ZNF316 | c.2279C>T p.S760L | Missense Mutation (SNP) | VAF 118/480 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- ZNFX1 | c.1687A>T p.N563Y | Missense Mutation (SNP) | VAF 30/399 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2
- CSMD1 | c.2982C>T p.S994= (on ENST00000520002; = p.S993= on NM_033225.6) | Silent (SNP) | VAF 282/987 reads (29%) | catalogued as rs372606827; called by muse, mutect2, varscan2
- JAKMIP1 | c.144C>T p.R48= | Silent (SNP) | VAF 24/344 reads (7%) | called by muse, mutect2
- MUC2 | chr11:1098608 A>G | 3'Flank (SNP) | VAF 94/492 reads (19%) | catalogued as rs1186298516; called by mutect2, varscan2
- NEDD4L | c.2427-29G>A | Intron (SNP) | VAF 13/228 reads (6%) | called by muse, mutect2
- WNK1 | c.-5C>T | 5'UTR (SNP) | VAF 104/275 reads (38%) | called by muse, mutect2, varscan2
